Somatic mutation profile of tumor specimen TCGA-D3-A5GU-06A (aliquot TCGA-D3-A5GU-06A-11D-A27K-08) from TCGA case TCGA-D3-A5GU, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 44.9 years (16,401 days).
Specimen TCGA-D3-A5GU-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41ab6b9b-1641-46be-ba2b-eb5a49164f40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A5GU-10A (Blood Derived Normal), aliquot TCGA-D3-A5GU-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b16a9e5-9bfa-4fa8-8be7-3766577ebd8f

The open-access MAF lists 889 somatic variants for this specimen: 599 protein-altering or splice-affecting, 273 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 529, Silent 273, Nonsense Mutation 45, Splice Site 8, Splice Region 7, Intron 6, Frame Shift Del 5, RNA 5, 3'UTR 3, 5'Flank 3, Translation Start Site 2, In Frame Del 2.

Variants (750 of 889; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PCED1B | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 92/243 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs757280610, COSV71394886, COSV71395186; called by muse, mutect2, varscan2
- ABAT | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs755955325, COSV51626741; called by muse, mutect2, varscan2
- ABCA12 | c.6203G>A p.G2068D (on ENST00000272895 / NM_173076.3; = p.G1750D on NM_015657.3) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as COSV55970794; called by muse, mutect2, varscan2
- ABCA8 | c.4220G>A p.G1407E | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779876120, COSV52209093; called by muse, mutect2, varscan2
- ABCB5 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs776087695, COSV51717447; called by muse, mutect2, varscan2
- AC008397.2 | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99441578; called by muse, mutect2, varscan2
- ACAP2 | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58754669; called by muse, mutect2, varscan2
- ADAM23 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV52225680; called by muse, mutect2, varscan2
- ADAM32 | c.2327C>T p.S776L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as COSV65952616; called by muse, mutect2, varscan2
- ADAM7 | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.75); catalogued as rs761799556, COSV51544716; called by muse, mutect2, varscan2
- ADAMTS2 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755997172, COSV51072403; called by muse, mutect2, varscan2
- ADAMTS3 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV54398991; called by muse, mutect2, varscan2
- ADCY6 | c.796G>A p.G266S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.09); catalogued as COSV100327070, COSV57169723; called by muse, mutect2, varscan2
- ADCY8 | c.1467G>A p.M489I | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.27); catalogued as COSV53921499; called by muse, mutect2, varscan2
- ADGRF2 | c.1237C>T p.Q413* (on ENST00000296862 / NM_001368115.2; = p.Q345* on NM_153839.7) | Nonsense Mutation (SNP) | VAF 40/138 reads (29%) | catalogued as rs757455480, COSV57287854, COSV57291068; called by muse, mutect2, varscan2
- ADGRV1 | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV67992694; called by muse, mutect2, varscan2
- ADGRV1 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67992696; called by muse, mutect2, varscan2
- ADH1B | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 73/443 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59295195; called by muse, mutect2, varscan2
- ADH6 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV52957345; called by muse, mutect2, varscan2
- ADNP2 | c.3340G>A p.D1114N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.051); catalogued as COSV51541540; called by muse, mutect2, varscan2
- AGAP1 | c.2485G>A p.E829K (on ENST00000304032 / NM_001037131.3; = p.E776K on NM_014914.5) | Missense Mutation (SNP) | VAF 56/94 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as rs774221910, COSV58336299; called by muse, mutect2
- AKAP8 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV54102486, COSV54104037; called by muse, mutect2, varscan2
- AKAP9 | c.5794C>T p.R1932* (on ENST00000359028; = p.R1900* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | catalogued as rs978219635, COSV62354761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH1B1 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV66620455; called by muse, mutect2, varscan2
- ALDH3B2 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 66/104 reads (63%) | catalogued as rs748206299, COSV100824024; called by muse, mutect2, varscan2
- ALK | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as rs1046338903, COSV66584122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALK | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); catalogued as COSV66566485; called by muse, mutect2, varscan2
- ALPK1 | c.2495C>T p.S832F | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.246); catalogued as rs1192623521, COSV51584218, COSV51589939; called by muse, mutect2, varscan2
- AMER3 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs747941390, COSV58469067; called by muse, mutect2, varscan2
- AMY2A | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 47/447 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1185757504, COSV70214228; called by muse, mutect2, varscan2
- ANAPC2 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60571798; called by muse, mutect2, varscan2
- ANAPC5 | c.1909C>T p.P637S | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.236); catalogued as COSV55844536; called by muse, mutect2, varscan2
- ANLN | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs576328951, COSV56074757, COSV56077152; called by muse, mutect2, varscan2
- ANP32D | c.281A>G p.N94S | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.2); catalogued as COSV56980848; called by muse, mutect2, varscan2
- APBA1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); catalogued as rs748594161, COSV55234593; called by muse, mutect2, varscan2
- APC | c.3805A>T p.I1269L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as CD011097, COSV57351281, COSV57369577; called by muse, mutect2, varscan2
- APOB | c.3746A>C p.Q1249P | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as COSV51947391; called by muse, mutect2, varscan2
- ARHGAP18 | c.691A>G p.N231D | Missense Mutation (SNP) | VAF 63/120 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.334); catalogued as COSV63765723; called by muse, mutect2, varscan2
- ARHGAP20 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 87/112 reads (78%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as rs1258805296, COSV52817183; called by muse, mutect2, varscan2
- ARHGEF39 | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58397909; called by muse, mutect2, varscan2
- ARID1B | c.5905C>T p.H1969Y | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as rs772582709, COSV51675216; called by muse, mutect2, varscan2
- ARID2 | c.1825C>T p.Q609* | Nonsense Mutation (SNP) | VAF 75/216 reads (35%) | catalogued as COSV57604341; called by muse, mutect2, varscan2
- ASIC1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1025157825, COSV57319640; called by muse, mutect2, varscan2
- ASXL3 | c.2393C>A p.T798N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as COSV52475413, COSV99326842; called by muse, mutect2, varscan2
- ASXL3 | c.5480C>T p.P1827L | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52459204; called by muse, mutect2, varscan2
- ATF7IP2 | c.1822G>T p.V608L | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV61094887; called by muse, mutect2, varscan2
- ATG7 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61614907; called by muse, mutect2, varscan2
- ATP11B | c.2065C>T p.R689* | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as rs1295948091, COSV60026923; called by muse, mutect2, varscan2
- ATP4A | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 107/204 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.509); catalogued as COSV52870789; called by muse, mutect2, varscan2
- ATP9B | c.397A>T p.N133Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100303391; called by muse, mutect2, varscan2
- ATP9B | c.3012+1G>A p.X1004_splice | Splice Site (SNP) | VAF 9/23 reads (39%) | catalogued as COSV56953779, COSV56958501; called by muse, mutect2, varscan2
- ATXN2 | c.2747C>T p.P916L (on ENST00000550104; = p.P756L on NM_002973.4) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV66482254; called by muse, mutect2, varscan2
- ATXN2 | c.2746C>T p.P916S (on ENST00000550104; = p.P756S on NM_002973.4) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV101112565; called by muse, mutect2, varscan2
- ATXN7L1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as rs898030060, COSV59495407; called by muse, mutect2, varscan2
- AVPR1A | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV54547673; called by muse, mutect2, varscan2
- BAP1 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 18/54 reads (33%) | catalogued as COSV56236997, COSV56239776; called by muse, mutect2, varscan2
- BAZ2B | c.6472G>A p.E2158K | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV58607419; called by muse, mutect2, varscan2
- BCL11A | c.2355G>A p.M785I (on ENST00000335712 / NM_001365609.1; = p.M819I on NM_022893.4) | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs1485196223, COSV59635122; called by muse, mutect2, varscan2
- BCL2L2 | c.539T>A p.L180Q | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV99161512; called by muse, mutect2, varscan2
- BCL9 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 95/285 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV52343451; called by muse, mutect2, varscan2
- BICD1 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.145); catalogued as rs1212294612, COSV55685535; called by muse, mutect2, varscan2
- BPIFB4 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs757030605, COSV64951864, COSV64951994; called by muse, mutect2, varscan2
- BTN3A2 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV62688056; called by muse, mutect2, varscan2
- C11orf54 | c.689C>T p.S230F (on ENST00000331239; = p.S180F on NM_014039.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/87 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58679833; called by muse, mutect2, varscan2
- C16orf71 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); catalogued as rs762580874, COSV54794453; called by muse, mutect2, varscan2
- C4B | c.3390G>A p.G1130= | Splice Region (SNP) | VAF 27/157 reads (17%) | catalogued as COSV101312173; called by muse, mutect2, varscan2
- C4B | c.3391G>A p.G1131S | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101312174; called by muse, mutect2, varscan2
- C5 | c.1711C>T p.L571F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56331080; called by muse, mutect2, varscan2
- C6 | c.2659C>G p.Q887E | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as COSV54715694; called by muse, mutect2, varscan2
- CACNA1A | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64208267; called by muse, mutect2, varscan2
- CACNA1B | c.5179G>A p.D1727N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV53115478; called by muse, mutect2, varscan2
- CAMTA1 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV57920159; called by muse, mutect2, varscan2
- CAPNS2 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50898379, COSV50901994; called by mutect2, varscan2
- CAPSL | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs374502442; called by muse, mutect2, varscan2
- CATIP | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56823231; called by muse, mutect2, varscan2
- CCDC191 | c.2275A>T p.R759* | Nonsense Mutation (SNP) | VAF 50/164 reads (30%) | catalogued as COSV55675139; called by muse, mutect2, varscan2
- CCP110 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.467); catalogued as COSV66817751; called by muse, mutect2, varscan2
- CD163 | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 78/181 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.134); catalogued as COSV63136122; called by muse, mutect2, varscan2
- CD1E | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV63772397; called by muse, mutect2, varscan2
- CD28 | c.539G>A p.R180K | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100142447, COSV60731399; called by muse, mutect2, varscan2
- CD53 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV54762619; called by muse, varscan2
- CDC42EP3 | c.515G>A p.W172* | Nonsense Mutation (SNP) | VAF 32/118 reads (27%) | catalogued as COSV54875355; called by muse, mutect2, varscan2
- CDH5 | c.2057C>T p.A686V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); catalogued as rs543410829, COSV58519277; called by muse, mutect2, varscan2
- CDH6 | c.2315C>G p.P772R | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54075913; called by muse, mutect2, varscan2
- CENPF | c.7142G>A p.R2381K | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as COSV100871859, COSV65277959; called by muse, mutect2, varscan2
- CEP131 | c.1756G>A p.A586T (on ENST00000269392 / NM_001319228.2; = p.A583T on NM_014984.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.472); catalogued as COSV53955519; called by muse, mutect2, varscan2
- CEP70 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 23/61 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV53877521; called by muse, mutect2, varscan2
- CER1 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV66603838; called by muse, mutect2
- CFAP54 | c.7399G>A p.G2467R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.346); catalogued as rs1565962229, COSV61574271; called by muse, mutect2
- CFAP58 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.671); catalogued as COSV57213232; called by muse, mutect2, varscan2
- CFHR1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.218); catalogued as COSV100258548, COSV57628478; called by muse, mutect2, varscan2
- CFHR4 | c.33G>T p.L11F | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.939); catalogued as COSV52233993; called by muse, mutect2, varscan2
- CHL1 | c.917G>A p.G306E (on ENST00000397491 / NM_001253387.1; = p.G322E on NM_006614.4) | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56586497; called by muse, mutect2, varscan2
- CHRM2 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV57764804, COSV57765460; called by muse, mutect2, varscan2
- CHST8 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV52856837; called by muse, mutect2, varscan2
- CIITA | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs199476065, COSV60860754; ClinVar: not provided; called by muse, mutect2, varscan2
- CLIC6 | c.1441G>A p.G481S (on ENST00000360731 / NM_001317009.2; = p.G463S on NM_053277.3) | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV62448922; called by muse, mutect2, varscan2
- CLPTM1L | c.529A>T p.N177Y | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.285); catalogued as COSV57992137; called by muse, mutect2
- CMTM8 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV104409520, COSV56779330; called by muse, mutect2, varscan2
- CNGB3 | c.794T>G p.L265R | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60695713; called by muse, mutect2, varscan2
- CNTF | c.503G>A p.W168* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as COSV60158715; called by muse, mutect2, varscan2
- CNTF | c.504G>A p.W168* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as COSV100284460; called by muse, mutect2, varscan2
- CNTNAP5 | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV70494474; called by muse, mutect2, varscan2
- COL12A1 | c.6032G>A p.G2011E | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV59404325; called by muse, mutect2, varscan2
- COL14A1 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52864368; called by muse, mutect2, varscan2
- COL22A1 | c.2789G>A p.S930N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.533); catalogued as COSV57353339, COSV57356357; called by muse, mutect2, varscan2
- COL4A4 | c.3331C>T p.Q1111* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV61635127; called by muse, mutect2, varscan2
- COL4A4 | c.1706G>A p.G569E | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61635131; called by muse, mutect2, varscan2
- COL8A1 | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53740044; called by muse, mutect2, varscan2
- COL9A1 | c.168G>A p.G56= | Splice Region (SNP) | VAF 8/26 reads (31%) | catalogued as rs1324002690, COSV61836513; called by muse, mutect2, varscan2
- COMP | c.1934G>A p.G645D | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55876165; called by muse, mutect2, varscan2
- CPNE9 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56069437; called by muse, mutect2, varscan2
- CRISP2 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 77/146 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100189227, COSV59256387; called by muse, mutect2, varscan2
- CRLF2 | c.138G>A p.W46* | Nonsense Mutation (SNP) | VAF 86/148 reads (58%) | catalogued as rs1319179000, COSV101053685; called by muse, mutect2, varscan2
- CRLF2 | c.137G>A p.W46* | Nonsense Mutation (SNP) | VAF 87/151 reads (58%) | catalogued as COSV67494438; called by muse, mutect2, varscan2
- CRP | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 320/602 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54814363; called by muse, mutect2, varscan2
- CSF2RA | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV62626262; called by muse, mutect2, varscan2
- CSF3R | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV58970242; called by muse, mutect2, varscan2
- CSMD3 | c.5792C>T p.S1931F (on ENST00000297405 / NM_001363185.1; = p.S1827F on NM_052900.3) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV52198534; called by muse, mutect2, varscan2
- CSMD3 | c.1591G>A p.E531K (on ENST00000297405 / NM_001363185.1; = p.E427K on NM_052900.3) | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV52152676; called by muse, mutect2, varscan2
- CTDP1 | c.1237C>A p.P413T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV50010501, COSV99310448; called by muse, mutect2, varscan2
- CTDP1 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV99310451; called by muse, mutect2, varscan2
- CTNNAL1 | c.1525G>T p.E509* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV57704777; called by muse, mutect2, varscan2
- CXXC5 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.182); catalogued as COSV56795125; called by muse, mutect2, varscan2
- CYFIP2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.305); catalogued as rs753263281, COSV59027684; called by muse, mutect2, varscan2
- CYP21A2 | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.049); catalogued as rs1458675296, CD161369, COSV64486244; called by muse, mutect2, varscan2
- DACH2 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 37/44 reads (84%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.519); catalogued as COSV64181231; called by muse, mutect2, varscan2
- DBF4 | c.1750C>T p.R584* | Nonsense Mutation (SNP) | VAF 48/98 reads (49%) | catalogued as rs144858770; called by muse, mutect2, varscan2
- DCDC2 | c.518T>C p.V173A | Missense Mutation (SNP) | VAF 101/352 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV65833469; called by muse, mutect2, varscan2
- DCST2 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV99791841; called by muse, mutect2, varscan2
- DENND2A | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV52051453; called by muse, mutect2, varscan2
- DGKI | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs760167594, COSV55937658; called by muse, mutect2, varscan2
- DHRS13 | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV66684264; called by muse, mutect2, varscan2
- DIAPH1 | c.2296G>A p.G766R | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs769148092, COSV53887183; called by muse, mutect2, varscan2
- DISP2 | c.3704C>T p.S1235F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1325628681, COSV51136239; called by muse, mutect2, varscan2
- DMD | c.9130G>A p.D3044N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754722195, COSV58955377; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH3 | c.6829G>A p.D2277N | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780707324, COSV54504614; called by muse, mutect2, varscan2
- DNAH5 | c.11233C>T p.H3745Y | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV54208394; called by muse, mutect2, varscan2
- DNAH5 | c.9730G>A p.E3244K | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV54223192, COSV54229346; called by muse, mutect2, varscan2
- DNAH5 | c.4488G>A p.W1496* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as COSV99448753; called by muse, mutect2, varscan2
- DNAH5 | c.4487G>A p.W1496* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV99448756; called by muse, mutect2, varscan2
- DNAH5 | c.1238C>T p.T413I | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV54244545; called by muse, mutect2, varscan2
- DNAH8 | c.4870G>A p.D1624N | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV59426912; called by muse, mutect2, varscan2
- DNAH9 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs1455999150, COSV52368970; called by muse, mutect2, varscan2
- DNAI3 | c.1662T>A p.F554L | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.397); catalogued as COSV54005015; called by muse, mutect2, varscan2
- DNASE2B | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 44/80 reads (55%) | catalogued as rs756655416, COSV65737803; called by muse, mutect2, varscan2
- DNM3 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV62464431; called by muse, mutect2, varscan2
- DOCK3 | c.849G>A p.M283I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV56506346; called by muse, mutect2, varscan2
- DSCAML1 | c.3988T>A p.S1330T (on ENST00000321322; = p.S1270T on NM_020693.4) | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV58399539; called by muse, mutect2, varscan2
- DTNB | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.964); catalogued as COSV56482229; called by muse, mutect2, varscan2
- EDNRA | c.857G>A p.R286K | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.147); catalogued as COSV60099668; called by muse, mutect2, varscan2
- EDNRB | c.1154T>C p.L385P (on ENST00000377211 / NM_001201397.1; = p.L295P on NM_000115.5) | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV57526748; called by muse, mutect2, varscan2
- EEPD1 | c.815C>G p.S272C | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54202099; called by muse, mutect2, varscan2
- EFHC2 | c.1166G>A p.R389K | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV69555024; called by muse, mutect2, varscan2
- EFS | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs753502762, COSV53732607, COSV53733823; called by muse, mutect2, varscan2
- EIF4A1 | c.10A>T p.S4C | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.283); catalogued as COSV53445045; called by muse, mutect2, varscan2
- ELMO3 | c.718C>T p.P240S (on ENST00000652269; = p.P187S on NM_024712.5) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV62607437; called by muse, mutect2, varscan2
- ELOA2 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV55295883; called by muse, mutect2, varscan2
- EMB | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.373); catalogued as rs375679309; called by muse, mutect2, varscan2
- EMB | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV57480680; called by muse, mutect2, varscan2
- EML1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV99214886; called by muse, mutect2, varscan2
- EML1 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99214889; called by muse, mutect2, varscan2
- ENTR1 | c.545C>T p.T182I (on ENST00000357365 / NM_001039707.2; = p.T159I on NM_006643.4) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV53742731; called by muse, mutect2, varscan2
- EPRS1 | c.2666G>A p.R889K | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65100904; called by muse, mutect2, varscan2
- ERC2 | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV55651645; called by muse, mutect2, varscan2
- F13A1 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as CM054666, COSV99342795; called by muse, mutect2, varscan2
- F5 | c.3235C>T p.P1079S | Missense Mutation (SNP) | VAF 87/294 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV63126682; called by muse, mutect2, varscan2
- FAM20C | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs779708323, CM091203, COSV100570698, COSV58234675; called by muse, mutect2, varscan2
- FAM20C | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV100570353; called by muse, mutect2, varscan2
- FAM3A | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as COSV59194847; called by muse, mutect2, varscan2
- FANCG | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as COSV62721826; called by muse, mutect2, varscan2
- FASN | c.6686C>T p.P2229L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100147666; called by muse, mutect2
- FASN | c.6685C>T p.P2229S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.285); catalogued as COSV100147667; called by muse, mutect2
- FASN | c.1972G>A p.V658M | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.584); catalogued as COSV60759431; called by muse, mutect2, varscan2
- FAT2 | c.12518-1G>A p.X4173_splice | Splice Site (SNP) | VAF 31/133 reads (23%) | catalogued as COSV99942566; called by muse, mutect2, varscan2
- FAT4 | c.5705G>A p.R1902Q | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.991); catalogued as rs367572465, COSV58695856; called by muse, mutect2, varscan2
- FBRS | c.12A>T p.K4N (on ENST00000287468; = p.K524N on NM_001105079.3) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54918091; called by muse, mutect2, varscan2
- FBXW12 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.153); catalogued as COSV56485042; called by muse, mutect2, varscan2
- FER1L6 | c.4358G>A p.R1453Q | Missense Mutation (SNP) | VAF 87/236 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs560213365, COSV67549074; called by muse, mutect2, varscan2
- FGD4 | c.1795C>T p.Q599* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV56782117; called by muse, mutect2, varscan2
- FGG | c.630C>G p.I210M | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.488); catalogued as rs148688900, COSV60195003, COSV60196402; called by muse, mutect2, varscan2
- FHOD3 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV57183721; called by muse, mutect2, varscan2
- FLNB | c.2120C>T p.S707L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.2); catalogued as rs780137252, COSV55891222; called by muse, mutect2, varscan2
- FLT4 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as rs776682740, COSV56097112, COSV56105069; called by muse, mutect2, varscan2
- FMO3 | c.1469G>A p.W490* | Nonsense Mutation (SNP) | VAF 25/98 reads (26%) | catalogued as COSV63008221; called by muse, mutect2, varscan2
- FN3KRP | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.068); catalogued as rs781050743, COSV53931125; called by muse, mutect2, varscan2
- FNBP4 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV55451238, COSV55452092; called by muse, mutect2, varscan2
- FOLR2 | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 19/20 reads (95%) | catalogued as rs750713005, COSV53352192; called by muse, mutect2, varscan2
- FOXF1 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV52288168; called by muse, mutect2
- FSIP2 | c.18997G>A p.E6333K | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.918); catalogued as rs867705713, COSV58080987; called by muse, mutect2, varscan2
- FSTL5 | c.2174G>A p.G725E | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60219307; called by muse, mutect2, varscan2
- GABRA5 | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV59478815, COSV59484071; called by muse, mutect2, varscan2
- GABRB1 | c.1014A>T p.K338N | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99781200; called by muse, mutect2, varscan2
- GABRB1 | c.1015A>C p.K339Q | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.997); catalogued as COSV99781203; called by muse, mutect2, varscan2
- GABRB2 | c.1358G>A p.R453Q (on ENST00000274547; = p.R415Q on NM_000813.3) | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs371728438; called by muse, mutect2, varscan2
- GADL1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV56983735; called by muse, mutect2, varscan2
- GALNTL5 | c.56G>A p.W19* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as COSV67180867; called by muse, mutect2, varscan2
- GBP5 | c.754C>G p.P252A | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.102); catalogued as COSV58593986; called by muse, mutect2, varscan2
- GCSAML | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867795960, COSV63577305; called by muse, mutect2, varscan2
- GHR | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867392523, COSV50109830, COSV50135382; called by muse, mutect2, varscan2
- GK2 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1417995112, COSV62626181; called by muse, mutect2, varscan2
- GLRA3 | c.793C>G p.L265V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV56867708; called by muse, mutect2, varscan2
- GLT6D1 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.056); catalogued as COSV65628259; called by muse, mutect2, varscan2
- GPC5 | c.1562G>A p.W521* | Nonsense Mutation (SNP) | VAF 25/83 reads (30%) | catalogued as COSV65619526; called by muse, mutect2, varscan2
- GPR142 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV59520143; called by muse, mutect2, varscan2
- GPRIN3 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 82/184 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV60886118; called by muse, mutect2, varscan2
- GPX5 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT tolerated (0.8); PolyPhen benign (0.02); catalogued as rs1308994203, COSV69079772; called by muse, mutect2, varscan2
- GRB14 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55741781; called by muse, mutect2, varscan2
- GRB14 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55740624; called by muse, mutect2, varscan2
- GRIN2D | c.2437G>T p.D813Y | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53520309; called by muse, mutect2, varscan2
- GRK2 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 92/123 reads (75%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV57952783; called by muse, mutect2, varscan2
- GRK4 | c.323G>A p.R108K (on ENST00000398052 / NM_182982.3; = p.R76K on NM_005307.3) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61670598; called by muse, mutect2
- GRM8 | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as COSV100285088, COSV58856500; called by muse, mutect2, varscan2
- GSDME | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.444); catalogued as COSV56041497; called by muse, mutect2, varscan2
- GUCY2C | c.2754G>A p.W918* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV53789611; called by muse, varscan2
- GUCY2C | c.2714G>A p.G905E | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV53794150; called by muse, varscan2
- HCFC2 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.265); catalogued as COSV57559909; called by muse, mutect2, varscan2
- HDGFL2 | c.678+1G>T p.X226_splice | Splice Site (SNP) | VAF 29/87 reads (33%) | catalogued as COSV56684472; called by muse, varscan2
- HEATR1 | c.4094C>T p.S1365F | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV63982592; called by muse, mutect2, varscan2
- HENMT1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV64230589; called by muse, mutect2, varscan2
- HES6 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs1187969802, COSV56029180; called by muse, mutect2, varscan2
- HEY2 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs531916278, COSV64240521; called by muse, mutect2, varscan2
- HGF | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 37/74 reads (50%) | catalogued as COSV55950843; called by muse, mutect2, varscan2
- HNRNPA0 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.332); catalogued as rs1407349156, COSV100152899; called by muse, mutect2, varscan2
- HNRNPUL2 | c.2105A>T p.Y702F | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100079558; called by muse, mutect2, varscan2
- HOXD1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs760740531, COSV58924260; called by muse, varscan2
- HRC | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV53258206; called by muse, mutect2, varscan2
- HSPA4 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV59183312; called by muse, mutect2, varscan2
- HYDIN | c.10417A>G p.N3473D | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV66883536; called by muse, mutect2, varscan2
- ICAM4 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1344883665, COSV53426589; called by muse, mutect2, varscan2
- IFNA7 | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as rs748785123, COSV53331988; called by muse, mutect2, varscan2
- IGF2BP1 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.378); catalogued as rs368120375, COSV99288730; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 141/556 reads (25%) | SIFT tolerated (0.97); PolyPhen benign (0.009); catalogued as rs1433689836; called by muse, mutect2, varscan2
- IGSF21 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52132239, COSV99244507; called by muse, mutect2, varscan2
- IGSF21 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV52144502; called by muse, mutect2, varscan2
- IGSF9 | c.2422G>A p.G808R (on ENST00000368094 / NM_001135050.2; = p.G792R on NM_020789.4) | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.45); PolyPhen benign (0.174); catalogued as COSV57423149; called by muse, mutect2, varscan2
- IL13RA2 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1556508440, COSV54567069; called by muse, mutect2, varscan2
- IL1RL1 | c.809A>T p.E270V | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV52119341; called by muse, mutect2, varscan2
- IL22 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1281179646, COSV60160600; called by muse, mutect2, varscan2
- INTS4 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 80/119 reads (67%) | SIFT tolerated (0.73); PolyPhen benign (0.133); catalogued as COSV71090904; called by muse, mutect2, varscan2
- INVS | c.2525G>A p.G842E | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV52447616; called by muse, mutect2, varscan2
- IRF6 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV65420140; called by muse, mutect2, varscan2
- IRS4 | c.2998C>T p.L1000F | Missense Mutation (SNP) | VAF 89/101 reads (88%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV64535388, COSV64536266; called by muse, mutect2, varscan2
- ITGA10 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782610320, COSV65197730; called by muse, mutect2, varscan2
- ITGB8 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480929101, COSV56012557; called by muse, mutect2, varscan2
- JAG1 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV54761261; called by muse, mutect2, varscan2
- JOSD2 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67119428; called by muse, mutect2, varscan2
- KANSL1L | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as COSV55995593; called by muse, mutect2, varscan2
- KCNA5 | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52907904; called by muse, mutect2, varscan2
- KCNB2 | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV73051062; called by muse, mutect2, varscan2
- KIAA0586 | c.3122C>T p.P1041L (on ENST00000619416 / NM_001244190.2; = p.P980L on NM_014749.5) | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV54180633; called by muse, mutect2, varscan2
- KIAA1210 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV68179217; called by muse, mutect2, varscan2
- KIAA1217 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56818228; called by muse, mutect2, varscan2
- KIAA1217 | c.2747C>T p.S916F | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV56821434; called by muse, mutect2, varscan2
- KIF1C | c.2500C>T p.R834W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as rs575669774, COSV100297279, COSV57906839; called by muse, mutect2
- KIF9 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV55522573; called by muse, mutect2, varscan2
- KIZ | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV55687316; called by muse, mutect2, varscan2
- KL | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as COSV66309559, COSV66309662; called by muse, mutect2, varscan2
- KLHDC8A | c.743T>A p.F248Y | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.931); catalogued as COSV65679167; called by muse, mutect2, varscan2
- KLHL4 | c.598C>T p.L200F | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64146376; called by muse, mutect2, varscan2
- KLHL9 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62922319; called by muse, mutect2, varscan2
- KLK4 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100133568, COSV60676924; called by muse, mutect2, varscan2
- KPNA4 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.211); catalogued as COSV62076672; called by muse, mutect2, varscan2
- KPTN | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.023); catalogued as COSV100583424; called by muse, mutect2, varscan2
- L3MBTL2 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1204966466, COSV53431435, COSV53433040; called by muse, mutect2, varscan2
- L3MBTL4 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs369119792; called by muse, mutect2, varscan2
- LACC1 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV57828960; called by muse, mutect2, varscan2
- LAMC3 | c.3492G>A p.R1164= | Splice Region (SNP) | VAF 13/50 reads (26%) | catalogued as rs1365220452, COSV63094391; called by muse, mutect2, varscan2
- LARS1 | c.584T>A p.M195K (on ENST00000394434 / NM_020117.11; = p.M168K on NM_016460.3) | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV50975559, COSV50984672; called by muse, varscan2
- LCTL | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs143302973, COSV58421500; called by muse, mutect2, varscan2
- LDB1 | c.853C>T p.P285S (on ENST00000425280 / NM_001321612.2; = p.P249S on NM_003893.5) | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV100756372; called by muse, mutect2, varscan2
- LENG8 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs143651422; called by muse, mutect2, varscan2
- LEPR | c.1705C>A p.Q569K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100756541; called by muse, mutect2, varscan2
- LEPR | c.1706A>T p.Q569L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100756542; called by muse, mutect2, varscan2
- LGR6 | c.1532C>T p.P511L (on ENST00000367278 / NM_001017403.1; = p.P459L on NM_021636.3) | Missense Mutation (SNP) | VAF 68/118 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.101); catalogued as rs1258239012, COSV55164023, COSV99706904; called by muse, mutect2, varscan2
- LILRB5 | c.1489C>T p.P497S (on ENST00000449561 / NM_001081442.3; = p.P496S on NM_006840.5) | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.779); catalogued as COSV60256514, COSV60260126; called by muse, mutect2, varscan2
- LMAN1L | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV59003067; called by muse, mutect2, varscan2
- LPA | c.3518G>A p.G1173E | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs535505150, COSV60308579; called by muse, mutect2, varscan2
- LRBA | c.1717C>T p.L573F | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63961630; called by muse, mutect2, varscan2
- LRIG2 | c.2312C>T p.T771I | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV63163565; called by muse, mutect2, varscan2
- LRP1 | c.11653C>T p.H3885Y | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV99675558; called by muse, mutect2, varscan2
- LRRC37A3 | c.1303C>T p.H435Y | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.097); catalogued as rs1207305950, COSV100141006; called by mutect2, varscan2
- LRRC40 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761206014, COSV100918748; called by muse, mutect2, varscan2
- LRRC45 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs566234490, COSV100141670, COSV100141790; called by muse, mutect2, varscan2
- LRRC55 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV73006863; called by muse, mutect2, varscan2
- LRRC8C | c.1626A>C p.K542N | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.275); catalogued as COSV65000230; called by muse, mutect2, varscan2
- LRRIQ3 | c.1707G>A p.M569I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1179689038, COSV63042900; called by muse, mutect2, varscan2
- LY75 | c.2867T>G p.I956S | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV55111111; called by muse, mutect2, varscan2
- MACO1 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV65477758; called by muse, mutect2, varscan2
- MAGEB2 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV66780260, COSV66782181; called by muse, mutect2, varscan2
- MAGT1 | c.409C>T p.P137S (on ENST00000618282 / NM_001367916.1; = p.P169S on NM_032121.5) | Missense Mutation (SNP) | VAF 73/89 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63780888; called by muse, mutect2, varscan2
- MAN1A2 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as rs757433812, COSV62976389; called by muse, mutect2, varscan2
- MAN2B2 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs1287834954, COSV53455521; called by muse, mutect2, varscan2
- MAP1LC3B | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV51785479; called by muse, mutect2, varscan2
- MAP3K21 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as rs753079246, COSV64045846; called by muse, varscan2
- MAP4K5 | c.1217T>C p.F406S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV50158854; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV51725141; called by muse, mutect2, varscan2
- MAPKBP1 | c.722G>A p.R241K | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV52965958; called by muse, mutect2, varscan2
- MCM3AP | c.4531G>A p.E1511K | Missense Mutation (SNP) | VAF 54/323 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as COSV52444098; called by muse, mutect2, varscan2
- MCTP1 | c.2520G>C p.L840F | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as rs972292230, COSV56528603, COSV56532352; called by muse, mutect2, varscan2
- MDFIC | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as rs145223906; called by muse, mutect2, varscan2
- MDN1 | c.6400C>T p.L2134F | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV101021194, COSV101021682; called by muse, mutect2, varscan2
- MEIS1 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV55490814; called by muse, mutect2
- MERTK | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs900547007, COSV54933994; called by muse, mutect2, varscan2
- METTL7A | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59840385, COSV59841184; called by muse, mutect2, varscan2
- MINDY4 | c.244T>G p.F82V | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV54677338; called by muse, mutect2, varscan2
- MKX | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs772891422, COSV65391454; called by muse, mutect2, varscan2
- MORC2 | c.1735C>T p.Q579* (on ENST00000397641 / NM_001303256.3; = p.Q517* on NM_014941.3) | Nonsense Mutation (SNP) | VAF 80/145 reads (55%) | catalogued as COSV53201539; called by muse, mutect2, varscan2
- MPRIP | c.422G>A p.W141* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | catalogued as COSV100505604; called by muse, mutect2, varscan2
- MPRIP | c.423G>T p.W141C | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100505606; called by muse, mutect2, varscan2
- MS4A12 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 90/137 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs867365250, COSV50015228; called by muse, mutect2, varscan2
- MS4A2 | c.636+1G>A p.X212_splice | Splice Site (SNP) | VAF 24/31 reads (77%) | catalogued as rs757675551, COSV54013503; called by muse, mutect2, varscan2
- MTNR1A | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV56155323; called by muse, mutect2, varscan2
- MUC16 | c.24464G>A p.R8155K | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.246); catalogued as COSV101200367, COSV67482088; called by muse, mutect2, varscan2
- MUC16 | c.14602G>A p.E4868K | Missense Mutation (SNP) | VAF 82/183 reads (45%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.205); catalogued as COSV67484099; called by muse, mutect2, varscan2
- MUC16 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as rs573506587, COSV67484109; called by muse, mutect2, varscan2
- MXRA5 | c.6937G>A p.E2313K | Missense Mutation (SNP) | VAF 128/140 reads (91%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.971); catalogued as rs1174165543, COSV54223661; called by muse, mutect2, varscan2
- MYBPC3 | c.2024G>A p.G675E | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57024375; called by muse, mutect2, varscan2
- MYCBP2 | c.8903T>C p.F2968S (on ENST00000357337; = p.F3006S on NM_015057.5) | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV62033681; called by muse, mutect2, varscan2
- MYCBP2 | c.6724C>T p.R2242C (on ENST00000357337; = p.R2280C on NM_015057.5) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs746498302, COSV62011622; called by muse, mutect2, varscan2
- MYCBP2 | c.2978C>T p.P993L (on ENST00000357337; = p.P1031L on NM_015057.5) | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV62033709; called by muse, mutect2, varscan2
- MYCT1 | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); catalogued as COSV100924059; called by muse, mutect2, varscan2
- MYCT1 | c.533T>A p.V178E | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.698); catalogued as COSV100924060; called by muse, mutect2, varscan2
- MYDGF | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1477596218, COSV53561376; called by muse, mutect2, varscan2
- MYLK | c.3088A>G p.K1030E | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.116); catalogued as COSV60618638; called by muse, mutect2, varscan2
- MYO18B | c.6596G>C p.R2199P | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV59144486; called by muse, mutect2, varscan2
- MYRIP | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56878100; called by muse, mutect2, varscan2
- MYT1L | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as COSV67728929; called by muse, mutect2, varscan2
- NCAN | c.2765C>T p.P922L | Missense Mutation (SNP) | VAF 75/212 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs751900603, COSV53056294; called by muse, mutect2, varscan2
- NDFIP2 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV54529507; called by muse, mutect2, varscan2
- NELFB | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs762179684, COSV58026077; called by muse, mutect2, varscan2
- NFS1 | c.1297C>T p.L433F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65054169; called by muse, mutect2, varscan2
- NFX1 | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.141); catalogued as rs2860036, COSV59312353; called by muse, mutect2, varscan2
- NFYC | c.1358C>T p.P453L (on ENST00000308733 / NM_001308114.1; = p.P330L on NM_014223.5) | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as COSV100438391; called by muse, mutect2, varscan2
- NLRP12 | c.1790G>A p.S597N | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs748314396, COSV60752529; called by muse, mutect2, varscan2
- NLRP8 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99405160; called by muse, mutect2, varscan2
- NLRP8 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs759131290, COSV52587344; called by muse, mutect2, varscan2
- NLRP9 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as rs1430197620, COSV60459475; called by muse, mutect2, varscan2
- NMRAL1 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 36/182 reads (20%) | catalogued as COSV99361730; called by muse, mutect2, varscan2
- NMRAL1 | c.174C>A p.D58E | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV99361732; called by muse, mutect2, varscan2
- NOP14 | c.2395G>T p.E799* | Nonsense Mutation (SNP) | VAF 94/305 reads (31%) | catalogued as COSV58627051; called by muse, mutect2, varscan2
- NOS1 | c.2564C>T p.S855F | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57618994; called by muse, mutect2, varscan2
- NOTCH3 | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54644588; called by muse, mutect2, varscan2
- NOTCH4 | c.2654C>T p.S885F | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1376525849, COSV66682965; called by muse, mutect2, varscan2
- NR0B2 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV54260070; called by muse, mutect2
- NR2E1 | c.642+2T>A p.X214_splice | Splice Site (SNP) | VAF 13/50 reads (26%) | catalogued as COSV64562575; called by muse, mutect2, varscan2
- NR4A2 | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100277117; called by muse, mutect2
- NRXN1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs200781129, COSV68032996, COSV99065640; called by muse, mutect2, varscan2
- NSUN2 | c.1750G>A p.G584R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV52956405; called by muse, mutect2, varscan2
- OBSCN | c.22711G>A p.D7571N | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV63096100; called by muse, mutect2, varscan2
- OCIAD2 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 125/312 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV56717269; called by muse, mutect2, varscan2
- OR10K2 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.147); catalogued as COSV100149755, COSV59222308; called by muse, mutect2, varscan2
- OR10Z1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 112/370 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1243889254, COSV63526049; called by muse, mutect2, varscan2
- OR2L3 | c.842C>T p.T281I | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as COSV63455992; called by muse, mutect2, varscan2
- OR2T10 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV57897902; called by muse, mutect2, varscan2
- OR2T4 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 183/400 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV63544834; called by muse, mutect2, varscan2
- OR52A1 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV61092070; called by muse, mutect2, varscan2
- OR5T3 | c.816G>A p.M272I | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV57381051, COSV57381505; called by muse, mutect2, varscan2
- OR6C2 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.093); catalogued as rs868176353, COSV59516658; called by muse, mutect2, varscan2
- OR7D4 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV58072224; called by muse, mutect2, varscan2
- ORC2 | c.826T>A p.L276M | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52240769; called by muse, mutect2, varscan2
- OSBPL3 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.017); catalogued as COSV57660908; called by muse, mutect2, varscan2
- OSBPL6 | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV51912060; called by muse, mutect2, varscan2
- OVGP1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758254920, COSV63858366; called by muse, mutect2, varscan2
- OXCT2 | c.1507T>C p.F503L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV59594427; called by muse, mutect2, varscan2
- PAN2 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 35/100 reads (35%) | catalogued as COSV57755434; called by muse, mutect2, varscan2
- PARD3 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 68/96 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60758188; called by muse, mutect2, varscan2
- PBX1 | c.455C>G p.A152G | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV61537985; called by muse, mutect2, varscan2
- PCDH1 | c.1693C>T p.Q565* | Nonsense Mutation (SNP) | VAF 26/50 reads (52%) | catalogued as COSV54613753; called by muse, mutect2, varscan2
- PCDHAC1 | c.982G>A p.V328M | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53864194; called by muse, mutect2, varscan2
- PCDHGA10 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV99536489; called by muse, mutect2, varscan2
- PCDHGB6 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 85/173 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV54006313; called by muse, mutect2, varscan2
- PCSK5 | c.787C>A p.Q263K | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV65094114; called by muse, mutect2, varscan2
- PCSK6 | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1432200891, COSV61858498; called by muse, mutect2, varscan2
- PDCD7 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52599676, COSV99200140; called by muse, mutect2, varscan2
- PDE6B | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.117); catalogued as rs1258894644, COSV99727377; called by muse, mutect2, varscan2
- PDZD2 | c.1868G>A p.G623E | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56868736; called by muse, mutect2, varscan2
- PEAR1 | c.207G>A p.T69= | Splice Region (SNP) | VAF 49/82 reads (60%) | catalogued as COSV52775086; called by muse, mutect2, varscan2
- PEG3 | c.2318C>T p.S773L | Missense Mutation (SNP) | VAF 92/177 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV55631658; called by muse, mutect2, varscan2
- PGBD1 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV52555392; called by muse, mutect2, varscan2
- PIK3C2A | c.2663C>T p.S888F | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV56405722; called by muse, mutect2, varscan2
- PIK3C2B | c.4396G>A p.E1466K | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as rs773476660, COSV65813551; called by muse, mutect2, varscan2
- PIK3C2G | c.1765G>A p.E589K (on ENST00000676171; = p.E548K on NM_004570.5) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs768619948, COSV56826233; called by muse, mutect2, varscan2
- PKD2L2 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51800340; called by muse, mutect2, varscan2
- PKDREJ | c.3457C>T p.H1153Y | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV53551948; called by muse, mutect2, varscan2
- PKHD1L1 | c.1450G>A p.V484I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs767434555, COSV65749947; called by muse, mutect2, varscan2
- PKN3 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs1045650856, COSV52579105; called by muse, mutect2, varscan2
- PLA2G7 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV51264273; called by muse, mutect2, varscan2
- PLB1 | c.2774G>A p.S925N | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.982); catalogued as COSV59833022; called by muse, mutect2, varscan2
- PLCB1 | c.180G>C p.E60D | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV62063120; called by muse, mutect2, varscan2
- PLSCR5 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs372938866; called by muse, mutect2, varscan2
- POF1B | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745416546, COSV53132451, COSV99427803; called by muse, mutect2
- POLR1E | c.373G>A p.E125K (on ENST00000377792 / NM_001282766.1; = p.E63K on NM_022490.4) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.765); catalogued as COSV66772828; called by muse, mutect2, varscan2
- POLR2M | c.955A>T p.N319Y | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); catalogued as COSV55211498; called by muse, mutect2, varscan2
- PPA2 | c.908C>T p.T303I (on ENST00000341695 / NM_176869.3; = p.T274I on NM_006903.4) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs759743241, COSV58997651; called by muse, mutect2, varscan2
- PPARGC1A | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 205/408 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.904); catalogued as COSV53532182; called by muse, mutect2, varscan2
- PRAG1 | c.2389C>T p.P797S | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.099); catalogued as COSV58161076; called by muse, mutect2, varscan2
- PREX1 | c.2465C>T p.S822L | Missense Mutation (SNP) | VAF 95/231 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV64255471; called by muse, mutect2, varscan2
- PREX2 | c.2863G>A p.G955R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1009630667, COSV99906653; called by muse, mutect2, varscan2
- PRMT8 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 152/357 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.242); catalogued as rs1459482390, COSV54217791; called by muse, mutect2, varscan2
- PRPH2 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 55/100 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57838275; called by muse, mutect2, varscan2
- PRUNE2 | c.5386G>A p.G1796R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs753455124, COSV65045959; called by muse, mutect2, varscan2
- PTCHD3 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as rs1430043831, COSV71257162; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.139G>A p.G47R (on ENST00000421990 / NM_001136042.2; = p.G29R on NM_025267.3) | Missense Mutation (SNP) | VAF 78/396 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV64184155; called by muse, mutect2, varscan2
- PTPN9 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100144258; called by muse, mutect2, varscan2
- PTPRF | c.4277C>T p.P1426L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63447700; called by muse, mutect2
- PTPRM | c.3494C>T p.S1165F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV59875276; called by muse, mutect2, varscan2
- PUS7 | c.1209G>A p.M403I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV62677782; called by muse, mutect2, varscan2
- PWWP3B | c.1173A>T p.E391D | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV61801187; called by muse, mutect2, varscan2
- PXDN | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.4); PolyPhen benign (0.065); catalogued as rs768133091, COSV53243394; called by muse, mutect2, varscan2
- PXDNL | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as rs758900873, COSV100681275, COSV62492958; called by mutect2, varscan2
- RAB11FIP5 | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 71/139 reads (51%) | catalogued as rs59033238; called by muse, mutect2, varscan2
- RAB37 | c.503C>T p.P168L (on ENST00000392613 / NM_001006638.3; = p.P161L on NM_175738.5) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV52854508; called by muse, mutect2, varscan2
- RAB40A | c.656G>A p.R219K | Missense Mutation (SNP) | VAF 128/156 reads (82%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV58491860; called by muse, mutect2, varscan2
- RABEP1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs773135833, COSV52587431; called by muse, mutect2, varscan2
- RAPGEF5 | c.958G>A p.D320N (on ENST00000401957 / NM_001367602.2; = p.D623N on NM_012294.5) | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV59785403, COSV59789427, COSV99070608; called by muse, mutect2, varscan2
- RARB | c.377G>A p.R126Q (on ENST00000383772 / NM_001290216.2; = p.R119Q on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as rs1292531557, COSV58070010; called by muse, mutect2, varscan2
- RC3H2 | c.2846C>T p.S949L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.879); catalogued as COSV61802005; called by muse, mutect2, varscan2
- RELN | c.2410G>A p.G804R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59026143; called by muse, mutect2, varscan2
- REST | c.2159C>T p.P720L | Missense Mutation (SNP) | VAF 179/414 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.039); catalogued as COSV58362237; called by muse, mutect2, varscan2
- RGS22 | c.2686C>T p.R896* | Nonsense Mutation (SNP) | VAF 28/64 reads (44%) | catalogued as rs772854946, COSV62660241; called by muse, mutect2, varscan2
- RHAG | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 88/137 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV57705754; called by muse, mutect2, varscan2
- RHBDD2 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.111); catalogued as COSV50088101; called by muse, mutect2, varscan2
- RHEX | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 74/232 reads (32%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.663); catalogued as COSV100520011, COSV58981568; called by muse, mutect2, varscan2
- RNFT2 | c.1098G>A p.Q366= | Splice Region (SNP) | VAF 34/77 reads (44%) | catalogued as COSV57489062; called by muse, mutect2, varscan2
- RP1 | c.2314G>A p.G772R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.082); catalogued as COSV55123782; called by muse, mutect2, varscan2
- RPL10A | c.80A>C p.K27T | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as COSV57690790; called by muse, mutect2, varscan2
- RPS19 | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 59/113 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as COSV55743912; called by muse, mutect2, varscan2
- RRNAD1 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs147288369, COSV100494096; called by muse, mutect2
- S100A16 | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV64182987; called by muse, mutect2, varscan2
- SALL1 | c.2849G>A p.R950K | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.535); catalogued as COSV51762633; called by muse, mutect2, varscan2
- SAMD7 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV59420563; called by muse, mutect2, varscan2
- SBNO1 | c.3173C>T p.S1058F (on ENST00000420886; = p.S1057F on NM_018183.5) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs375103435; called by muse, mutect2, varscan2
- SCG2 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV59541488; called by muse, mutect2, varscan2
- SCNN1B | c.1436G>C p.R479P | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV56303631, COSV56308647; called by muse, mutect2, varscan2
- SCP2 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65262119; called by muse, mutect2, varscan2
- SEC63 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.024); catalogued as rs267600758, COSV64601550; called by muse, mutect2, varscan2
- SELP | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as rs563523743, COSV55256343; called by muse, mutect2, varscan2
- SETBP1 | c.3134G>A p.G1045E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56332799; called by muse, mutect2, varscan2
- SFSWAP | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99906025; called by muse, mutect2, varscan2
- SFTPD | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 92/139 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142628179; called by muse, mutect2, varscan2
- SH2D4B | c.875G>A p.R292H (on ENST00000646907; = p.R291H on NM_207372.2) | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs372515371, COSV57899877; called by muse, mutect2, varscan2
- SH3BP4 | c.1229C>T p.T410I | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV60645636; called by muse, mutect2, varscan2
- SHANK2 | c.5321C>T p.S1774L | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV53613754; called by muse, mutect2, varscan2
- SHCBP1 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 25/122 reads (20%) | catalogued as rs764345009, COSV57646255; called by muse, mutect2, varscan2
- SHISA4 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100748219, COSV62884766; called by muse, mutect2
- SI | c.4158G>A p.M1386I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as COSV52294245; called by muse, mutect2, varscan2
- SLC12A7 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs780125830, COSV53761195; called by muse, mutect2, varscan2
- SLC22A14 | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as rs921908156, COSV99828206; called by muse, mutect2, varscan2
- SLC22A14 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV56197454; called by muse, mutect2, varscan2
- SLC24A1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 49/113 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as COSV56053482; called by muse, mutect2, varscan2
- SLC25A51 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as COSV54253084; called by muse, mutect2, varscan2
- SLC26A4 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as CM1211137, COSV55919019; called by muse, mutect2, varscan2
- SLC34A2 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as COSV65940894; called by muse, mutect2, varscan2
- SLC3A2 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV58604475; called by muse, mutect2
- SLC6A7 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57939944; called by muse, mutect2, varscan2
- SLC7A9 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs367824558; called by muse, mutect2, varscan2
- SMAD9 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.309); catalogued as rs1386703057, COSV63205984; called by muse, mutect2, varscan2
- SMYD1 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV70225755; called by muse, mutect2, varscan2
- SNAI3 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs141257304; called by muse, mutect2, varscan2
- SNX1 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56039474; called by muse, mutect2, varscan2
- SNX13 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.39); catalogued as COSV68067244; called by muse, mutect2, varscan2
- SNX19 | c.2021C>T p.S674F | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56287962; called by muse, mutect2, varscan2
- SOCS6 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67546964; called by muse, mutect2, varscan2
- SON | c.1871C>T p.P624L | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); catalogued as COSV51667669; called by muse, mutect2, varscan2
- SP140L | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.279); catalogued as rs1445344687, COSV54746837; called by muse, mutect2, varscan2
- SPACA9 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV62521884; called by muse, mutect2, varscan2
- SPAG1 | c.2649+1G>A p.X883_splice | Splice Site (SNP) | VAF 31/78 reads (40%) | catalogued as COSV52562180; called by muse, mutect2, varscan2
- SPAG8 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as COSV52415349; called by muse, mutect2, varscan2
- SPEF2 | c.2927G>A p.G976E | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV61547466; called by muse, mutect2
- SPG11 | c.1607G>A p.G536E | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200428589, COSV56000332; called by muse, mutect2, varscan2
- SPG21 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); catalogued as COSV52603653; called by muse, mutect2, varscan2
- SPRR2B | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 38/355 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV58796839; called by muse, mutect2
- SPRYD3 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as COSV56853330; called by muse, mutect2, varscan2
- SPTA1 | c.6808G>A p.E2270K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756666462, COSV63757545; called by muse, mutect2, varscan2
- SPTAN1 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV63989178; called by muse, mutect2, varscan2
- SPTBN4 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV58950862; called by muse, mutect2, varscan2
- SREBF2 | c.1927C>T p.Q643* | Nonsense Mutation (SNP) | VAF 37/78 reads (47%) | catalogued as COSV100761392; called by muse, mutect2, varscan2
- SRSF11 | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100918049, COSV63937585; called by muse, mutect2, varscan2
- SRSF6 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54828666; called by muse, mutect2, varscan2
- ST18 | c.1066A>G p.K356E | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52492606; called by muse, mutect2, varscan2
- ST3GAL1 | c.481G>C p.D161H | Missense Mutation (SNP) | VAF 49/142 reads (35%) | PolyPhen probably damaging (1); catalogued as rs1299742930, COSV60615419; called by muse, mutect2, varscan2
- ST7L | c.580T>A p.F194I | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.513); catalogued as COSV100573708, COSV58311368; called by muse, mutect2, varscan2
- STK24 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 80/191 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV64823422; called by muse, mutect2, varscan2
- STK32B | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51505080, COSV99286340; called by muse, mutect2, varscan2
- STK4 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.675); catalogued as COSV65671629; called by muse, mutect2, varscan2
- STOX2 | c.1448G>A p.R483K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.931); catalogued as rs751894934, COSV57855172; called by muse, mutect2
- SVEP1 | c.10048C>T p.P3350S | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52842615; called by muse, mutect2, varscan2
- SYT3 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as COSV58898421; called by muse, mutect2
- TACC2 | c.4742C>T p.P1581L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.112); catalogued as COSV57767738; called by muse, mutect2, varscan2
- TAF7L | c.1124T>A p.F375Y | Missense Mutation (SNP) | VAF 99/111 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV61257783; called by muse, mutect2, varscan2
- TARS1 | c.1903C>T p.Q635* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV54311516; called by muse, mutect2, varscan2
- TBC1D25 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 87/102 reads (85%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV65124338; called by muse, mutect2, varscan2
- TBC1D8B | c.1094G>A p.G365E | Missense Mutation (SNP) | VAF 133/149 reads (89%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as rs1199551687, COSV52182304; called by muse, mutect2, varscan2
- TBPL2 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1370123558, COSV55972166; called by muse, mutect2, varscan2
- TDP2 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV61968383; called by muse, mutect2, varscan2
- TEFM | c.948C>A p.F316L | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV58977328, COSV58977620; called by muse, mutect2, varscan2
- TEK | c.3344G>A p.G1115E | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1364520799, COSV66231989; called by muse, mutect2, varscan2
- TEKT5 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs761518800, COSV51586639; called by muse, mutect2, varscan2
- TELO2 | c.1894A>T p.T632S | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV51980378; called by muse, mutect2, varscan2
- TERT | c.2405G>A p.S802N | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV57232188; called by muse, mutect2, varscan2
- TEX15 | c.6370C>T p.L2124F (on ENST00000256246; = p.L2507F on NM_001350162.2) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1305666969, COSV56351748; called by muse, mutect2, varscan2
- THSD7B | c.2780T>C p.I927T | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV55723533; called by muse, mutect2, varscan2
- THSD7B | c.3110C>T p.P1037L | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs967125415, COSV55723546; called by muse, mutect2
- TIGD4 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as rs757414100, COSV58548890; called by muse, mutect2, varscan2
- TLN2 | c.427G>C p.G143R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.189); catalogued as COSV60893911; called by muse, varscan2
- TLR1 | c.1247A>C p.K416T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV58305256; called by muse, mutect2, varscan2
- TLR5 | c.2080G>A p.D694N | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs766055629, COSV60560234; called by muse, mutect2, varscan2
- TMEM52B | c.196C>T p.R66C (on ENST00000381923 / NM_001079815.1; = p.R46C on NM_153022.4) | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755716852, COSV100046370, COSV53729331; called by muse, mutect2, varscan2
- TMIGD3 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.501); catalogued as COSV62728778; called by muse, mutect2, varscan2
- TMPRSS2 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 70/118 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1386863611, COSV59826227; called by muse, mutect2, varscan2
- TMPRSS6 | c.-2G>A | Splice Region (SNP) | VAF 135/269 reads (50%) | catalogued as COSV100695690; called by muse, mutect2, varscan2
- TNNI3K | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.657); catalogued as COSV58562535; called by muse, mutect2, varscan2
- TNR | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 86/167 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54905885; called by muse, mutect2, varscan2
- TNRC6B | c.1189G>A p.G397R | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV100109527; called by muse, mutect2, varscan2
- TNRC6B | c.1190G>A p.G397E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV100109529; called by muse, mutect2, varscan2
- TNRC6C | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV56951093; called by muse, mutect2, varscan2
- TOX | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV63266567; called by muse, mutect2, varscan2
- TOX2 | c.511G>A p.A171T (on ENST00000358131 / NM_001098798.2; = p.A120T on NM_032883.3) | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs767742511, COSV57892912, COSV57893705; called by muse, mutect2, varscan2
- TP53TG5 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs779629018, COSV65578076; called by muse, mutect2, varscan2
- TP73 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100601155; called by muse, mutect2, varscan2
- TPH1 | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51459643; called by muse, mutect2
- TPTE2 | c.977G>A p.R326K (on ENST00000400230 / NM_199254.2; = p.R249K on NM_130785.3) | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55026097; called by muse, mutect2, varscan2
- TRAPPC3 | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.206); catalogued as COSV64264544; called by muse, mutect2, varscan2
- TRIM28 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as COSV53399325, COSV53401439; called by muse, mutect2, varscan2
- TRIM58 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63569964; called by muse, mutect2
- TRIO | c.4717G>A p.A1573T | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60091668; called by muse, mutect2, varscan2
- TRIP11 | c.2864C>T p.T955I | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as COSV99970595; called by muse, mutect2, varscan2
- TRPC6 | c.2486T>C p.V829A | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV60259124; called by muse, mutect2, varscan2
- TRPM3 | c.592C>T p.Q198* (on ENST00000357533 / NM_001366142.2; = p.Q43* on NM_020952.6) | Nonsense Mutation (SNP) | VAF 60/145 reads (41%) | catalogued as COSV62472862; called by muse, mutect2, varscan2
- TRPV4 | c.2337G>A p.R779= | Splice Region (SNP) | VAF 48/110 reads (44%) | catalogued as COSV55684429; called by muse, mutect2, varscan2
- TRUB1 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs768178093, COSV100076126, COSV53930791; called by muse, mutect2, varscan2
- TTC21A | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.096); catalogued as COSV57186359, COSV57188407; called by muse, mutect2, varscan2
- TTF2 | c.2909C>T p.S970F | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV101037413; called by muse, mutect2, varscan2
- TTN | c.93616G>A p.D31206N (on ENST00000591111; = p.D23782N on NM_003319.4) | Missense Mutation (SNP) | VAF 61/127 reads (48%) | PolyPhen probably damaging (0.998); catalogued as COSV60063160, COSV60259295; called by muse, mutect2, varscan2
- TTN | c.75334T>C p.Y25112H (on ENST00000591111; = p.Y17688H on NM_003319.4) | Missense Mutation (SNP) | VAF 105/193 reads (54%) | PolyPhen probably damaging (0.992); catalogued as COSV60259330; called by muse, mutect2, varscan2
- TTN | c.47215G>T p.D15739Y (on ENST00000591111; = p.D8315Y on NM_003319.4) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | PolyPhen probably damaging (0.912); catalogued as COSV60259368; called by muse, mutect2, varscan2
- TTN | c.44729C>T p.P14910L (on ENST00000591111; = p.P7486L on NM_003319.4) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | PolyPhen probably damaging (0.999); catalogued as rs1462000296, COSV60259410; called by muse, mutect2, varscan2
- TTN | c.22213C>T p.Q7405* (on ENST00000591111; = p.Q6478* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/28 reads (64%) | catalogued as COSV100625406, COSV60259449; called by muse, mutect2, varscan2
- TTN | c.6085G>A p.E2029K (on ENST00000591111; = p.E1983K on NM_003319.4) | Missense Mutation (SNP) | VAF 14/108 reads (13%) | PolyPhen benign (0.385); catalogued as COSV60259461; called by muse, mutect2, varscan2
- TTN | c.4277G>A p.R1426K (on ENST00000591111; = p.R1380K on NM_003319.4) | Missense Mutation (SNP) | VAF 26/52 reads (50%) | PolyPhen probably damaging (0.969); catalogued as COSV60259507; called by muse, mutect2, varscan2
- TUBG2 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99257509; called by muse, mutect2, varscan2
- U2SURP | c.2731G>T p.D911Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.446); catalogued as COSV67532623; called by muse, mutect2, varscan2
- UBA5 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778957097, COSV53905807; called by muse, mutect2, varscan2
- UBXN6 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.939); catalogued as rs771897085, COSV56675462; called by muse, mutect2, varscan2
- UGT2A3 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as COSV52361587; called by muse, mutect2, varscan2
- UGT2B15 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 77/167 reads (46%) | catalogued as rs145139175; called by muse, mutect2, varscan2
- UPB1 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as COSV58115355; called by muse, mutect2, varscan2
- USP29 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs372152335; called by muse, mutect2, varscan2
- WDFY3 | c.3938C>T p.P1313L | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55710712; called by muse, mutect2, varscan2
- WDR35 | c.1082G>A p.W361* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV55605713, COSV99029134; called by muse, mutect2, varscan2
- WNK2 | c.4924C>T p.P1642S (on ENST00000297954 / NM_001282394.1; = p.P1605S on NM_006648.3) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs778449894, COSV52955680; called by muse, mutect2
- WWP1 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.918); catalogued as COSV55362723; called by muse, mutect2, varscan2
- XCR1 | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.925); catalogued as COSV58570464; called by muse, mutect2
- XIRP1 | c.3037C>T p.Q1013* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV61140260; called by muse, mutect2, varscan2
- XKR3 | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58884846; called by muse, mutect2, varscan2
- XKR7 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.175); catalogued as COSV101629252; called by muse, mutect2, varscan2
- YTHDC1 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.346); catalogued as COSV60011633; called by muse, mutect2, varscan2
- YTHDF1 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV100945557; called by muse, mutect2, varscan2
- ZBED1 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 46/73 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58137681; called by muse, mutect2, varscan2
- ZBTB2 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 37/113 reads (33%) | catalogued as COSV57313716; called by muse, mutect2, varscan2
- ZBTB9 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 140/220 reads (64%) | SIFT tolerated (0.16); PolyPhen benign (0.135); catalogued as rs777018026, COSV67702339; called by muse, mutect2, varscan2
- ZCCHC17 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs201721345, COSV60003482; called by muse, mutect2, varscan2
- ZCWPW2 | c.805T>G p.L269V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV67500548; called by muse, mutect2, varscan2
- ZNF208 | c.54G>A p.W18* | Nonsense Mutation (SNP) | VAF 50/188 reads (27%) | catalogued as COSV68111008, COSV68111397; called by muse, mutect2, varscan2
- ZNF274 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 70/126 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as rs1433564705, COSV100465260, COSV58766086; called by muse, mutect2, varscan2
- ZNF32 | c.344G>A p.R115K | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV100986525, COSV65641878; called by muse, mutect2, varscan2
- ZNF341 | c.1757C>T p.P586L (on ENST00000375200 / NM_001282935.1; = p.P579L on NM_032819.4) | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV61010563; called by muse, mutect2, varscan2
- ZNF346 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 58/127 reads (46%) | catalogued as rs1339933585, COSV99993175; called by muse, mutect2, varscan2
- ZNF385D | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV55769420; called by muse, mutect2, varscan2
- ZNF415 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 33/66 reads (50%) | catalogued as COSV54703931; called by muse, mutect2, varscan2
- ZNF420 | c.1708C>A p.R570S | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.54); catalogued as COSV58493901, COSV58495635; called by muse, mutect2, varscan2
- ZNF451 | c.3172C>T p.L1058F (on ENST00000370706 / NM_001031623.3; = p.L1010F on NM_015555.2) | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV62599327; called by muse, mutect2, varscan2
- ZNF549 | c.727G>A p.G243R (on ENST00000376233 / NM_001199295.2; = p.G230R on NM_153263.2) | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.932); catalogued as rs775974644, COSV53727203; called by muse, mutect2, varscan2
- ZNF597 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57083684; called by muse, mutect2, varscan2
- ZNF598 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101461943; called by muse, mutect2, varscan2
- ZNF598 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101461944; called by muse, mutect2, varscan2
- ZNF624 | c.1396C>T p.H466Y | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60941115; called by muse, mutect2, varscan2
- ZNF662 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV100066271; called by muse, mutect2, varscan2
- ZNF662 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100066275, COSV60241357; called by muse, mutect2, varscan2
- ZNF687 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1164484813, COSV55020393; called by muse, mutect2, varscan2
- ZNF786 | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 99/238 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV60276062, COSV60277397; called by muse, mutect2, varscan2
- ZNF81 | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 44/49 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV58574831; called by muse, mutect2, varscan2
- ZNF878 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 110/276 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV72155893, COSV72155948; called by muse, varscan2
- CNNM1 | c.1758del p.K587Sfs*17 | Frame Shift Del (DEL) | VAF 41/95 reads (43%) | called by pindel, varscan2
- CUL5 | c.1781_1787del p.E594Afs*42 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- DICER1 | c.370_375del p.Y124_S125del | In Frame Del (DEL) | VAF 20/62 reads (32%) | called by mutect2, pindel, varscan2
- GFM2 | c.1500dup p.K501* | Frame Shift Ins (INS) | VAF 36/115 reads (31%) | called by mutect2, pindel, varscan2
- GTF2IRD2 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 71/113 reads (63%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MSMB | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 57/84 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSMB | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 58/86 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NACC2 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- NPLOC4 | c.644_654+12del p.X215_splice | Splice Site (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- OR56A1 | c.623_625delinsTC p.T208Ifs*18 | Frame Shift Del (DEL) | VAF 42/100 reads (42%) | called by pindel, varscan2*
- SNX19 | c.441_443delinsTG p.V148Gfs*12 | Frame Shift Del (DEL) | VAF 31/63 reads (49%) | called by pindel, varscan2*
- SPEN | c.6334_6335del p.R2112Gfs*10 | Frame Shift Del (DEL) | VAF 42/196 reads (21%) | called by pindel, varscan2
- URGCP | c.2519_2542del p.D840_R847del (on ENST00000453200 / NM_001077663.3; = p.D831_R838del on NM_017920.4) | In Frame Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- ZNF488 | c.631A>C p.K211Q | Missense Mutation (SNP) | VAF 53/62 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- AC008397.2 | c.1686C>T p.D562= | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as COSV99441581; called by muse, mutect2, varscan2
- ACTG1 | c.912C>T p.T304= | Silent (SNP) | VAF 35/150 reads (23%) | catalogued as rs782038116, COSV59511680; called by muse, mutect2, varscan2
- ADAM28 | c.1998C>T p.S666= | Silent (SNP) | VAF 88/201 reads (44%) | catalogued as rs199855027, COSV56103984; called by muse, mutect2, varscan2
- ADAM30 | c.1932C>T p.C644= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV65561802; called by muse, mutect2, varscan2
- ADAMTS16 | c.795C>T p.F265= | Silent (SNP) | VAF 110/280 reads (39%) | catalogued as COSV57002220; called by muse, mutect2, varscan2
- ADAMTS7 | c.924C>T p.H308= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as rs1207676370, COSV66308919; called by muse, mutect2, varscan2
- ADD2 | c.2143C>T p.L715= | Silent (SNP) | VAF 92/152 reads (61%) | catalogued as COSV52468199; called by muse, mutect2, varscan2
- ADGRV1 | c.11157C>T p.I3719= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as COSV67992700; called by muse, mutect2, varscan2
- AGO2 | c.1455C>T p.I485= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV55050979; called by muse, mutect2, varscan2
- ALDH3B2 | c.585C>G p.P195= | Silent (SNP) | VAF 66/102 reads (65%) | catalogued as COSV100824025; called by muse, mutect2, varscan2
- ALDOC | c.279C>T p.P93= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as COSV52025952; called by muse, mutect2, varscan2
- ARSF | c.906C>T p.F302= | Silent (SNP) | VAF 87/97 reads (90%) | catalogued as COSV63840679; called by muse, mutect2, varscan2
- ATP13A3 | c.1947C>T p.A649= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV55468358; called by muse, mutect2, varscan2
- ATP4A | c.1095G>A p.K365= | Silent (SNP) | VAF 111/219 reads (51%) | catalogued as COSV52870777; called by muse, mutect2, varscan2
- ATP9B | c.396G>A p.R132= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1222283726, COSV100303386; called by muse, mutect2, varscan2
- ATPAF1 | c.366G>T p.V122= (on ENST00000574428; = p.V145= on NM_022745.4) | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as COSV61305507; called by muse, mutect2, varscan2
- AVPR2 | c.309C>T p.D103= | Silent (SNP) | VAF 97/109 reads (89%) | catalogued as COSV61686778; called by muse, mutect2, varscan2
- B3GALNT1 | c.810C>T p.V270= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs779326139, COSV57579640; called by muse, mutect2
- B4GALNT1 | c.291C>T p.V97= | Silent (SNP) | VAF 104/248 reads (42%) | catalogued as COSV62042856; called by muse, mutect2, varscan2
- B4GALT1 | c.24G>A p.L8= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV65708704; called by muse, mutect2, varscan2
- BCL2L12 | c.51C>T p.F17= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs267605591, COSV55862539; called by muse, mutect2, varscan2
- BRIP1 | c.435C>T p.S145= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV51995942, COSV52006100; called by muse, mutect2, varscan2
- BRPF3 | c.2025C>T p.F675= | Silent (SNP) | VAF 67/129 reads (52%) | catalogued as rs867984122, COSV60209117; called by muse, mutect2, varscan2
- CABS1 | c.477C>T p.T159= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as COSV56734319; called by muse, mutect2, varscan2
- CACNG3 | c.273G>A p.Q91= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV50066474, COSV50084055; called by muse, mutect2, varscan2
- CALB2 | c.606G>A p.A202= | Silent (SNP) | VAF 49/196 reads (25%) | catalogued as rs756965535, COSV56940486; called by muse, mutect2, varscan2
- CCDC141 | c.2337C>T p.I779= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as COSV55370881, COSV55379622; called by muse, mutect2, varscan2
- CCN5 | c.261G>A p.R87= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV51938648; called by muse, mutect2
- CD1A | c.966G>A p.R322= | Silent (SNP) | VAF 47/269 reads (17%) | catalogued as COSV56862544; called by muse, mutect2, varscan2
- CDH24 | c.207C>T p.H69= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV52980245; called by muse, mutect2, varscan2
- CDH26 | c.2301C>T p.L767= (on ENST00000348616 / NM_177980.4; = p.L100= on NM_021810.6) | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as COSV54852064; called by muse, mutect2, varscan2
- CDHR2 | c.2025C>T p.L675= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs372497026; called by muse, mutect2, varscan2
- CEACAM16 | c.963C>T p.I321= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs748040042, COSV69188041; called by muse, mutect2, varscan2
- CFAP100 | c.1098C>A p.I366= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV61504174; called by muse, mutect2, varscan2
- CHAF1A | c.2727G>A p.E909= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV56675459; called by muse, mutect2, varscan2
- CKAP4 | c.1071C>T p.L357= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV65173113; called by muse, mutect2, varscan2
- CLPTM1L | c.531C>T p.N177= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as rs1186803024, COSV57990496; called by muse, mutect2
- CNTN4 | c.1824C>T p.I608= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV61878491; called by muse, mutect2, varscan2
- CNTNAP3 | c.3003C>T p.S1001= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs1256433400; called by muse, mutect2, varscan2
- COL7A1 | c.2466C>T p.L822= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV60401027; called by muse, mutect2, varscan2
- CPA6 | c.354G>A p.K118= | Silent (SNP) | VAF 74/200 reads (37%) | catalogued as COSV52733538, COSV52739188; called by muse, mutect2, varscan2
- CRB1 | c.2229C>T p.V743= | Silent (SNP) | VAF 37/66 reads (56%) | catalogued as COSV66332545; called by muse, mutect2, varscan2
- CRHBP | c.363G>A p.E121= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV57189574; called by muse, mutect2, varscan2
- CSF2RA | c.426G>A p.P142= | Silent (SNP) | VAF 80/199 reads (40%) | catalogued as rs770309852, COSV62624990; called by muse, mutect2, varscan2
- CTCF | c.84C>T p.R28= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs371652969; ClinVar: likely benign; called by muse, mutect2, varscan2
- CYP2J2 | c.438G>A p.R146= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV64605604; called by muse, mutect2, varscan2
- CYTIP | c.505C>T p.L169= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV51635338; called by muse, mutect2, varscan2
- DAPK2 | c.336C>T p.F112= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as rs144523094; called by muse, mutect2, varscan2
- DCBLD2 | c.1713C>T p.D571= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV58792223; called by muse, mutect2, varscan2
- DCHS1 | c.3570C>T p.P1190= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100201948, COSV55033814; called by muse, mutect2
- DCST2 | c.906C>T p.S302= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV99791836; called by mutect2, varscan2
- DCTD | c.444C>T p.A148= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs549336593, COSV63866826; called by muse, mutect2, varscan2
- DEFA3 | c.138C>T p.S46= | Silent (SNP) | VAF 28/305 reads (9%) | catalogued as COSV100590621, COSV100590645; called by muse, mutect2, varscan2
- DENND2A | c.1350C>T p.S450= | Silent (SNP) | VAF 52/271 reads (19%) | catalogued as COSV99326006; called by muse, mutect2, varscan2
- DEPDC5 | c.876C>T p.G292= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as rs267606229, COSV56706406; called by muse, mutect2, varscan2
- DMD | c.9129G>A p.R3043= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV58896217; called by muse, mutect2, varscan2
- DMD | c.6792G>A p.Q2264= | Silent (SNP) | VAF 61/73 reads (84%) | catalogued as CD972167, COSV58939690; called by muse, mutect2, varscan2
- DNAH1 | c.8262C>T p.A2754= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV70233969; called by mutect2, varscan2
- DNAH17 | c.9744C>T p.I3248= | Silent (SNP) | VAF 204/370 reads (55%) | catalogued as rs369453327, COSV67751911; called by muse, mutect2
- DNAH5 | c.1869C>T p.I623= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs752792992, COSV54204075; called by muse, mutect2, varscan2
- DRG2 | c.826C>T p.L276= | Silent (SNP) | VAF 24/237 reads (10%) | catalogued as COSV52762707; called by muse, mutect2, varscan2
- DSG3 | c.444G>A p.L148= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV57128630; called by muse, mutect2, varscan2
- DUOX2 | c.4485C>T p.F1495= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs556008835, COSV66531861; called by muse, mutect2, varscan2
- DYNC1LI2 | c.667C>T p.L223= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as rs763974153, COSV50755806; called by muse, mutect2, varscan2
- ECE1 | c.2307C>T p.V769= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV51662221, COSV51669065; called by muse, mutect2, varscan2
- EDDM3B | c.291G>A p.Q97= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV58747350; called by muse, mutect2, varscan2
- EPHA8 | c.1881T>C p.T627= | Silent (SNP) | VAF 132/221 reads (60%) | catalogued as COSV51287105; called by muse, mutect2, varscan2
- ETAA1 | c.1446G>A p.E482= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV55474857; called by muse, mutect2
- FABP3 | c.321G>A p.R107= | Silent (SNP) | VAF 110/229 reads (48%) | catalogued as COSV60003488; called by muse, mutect2, varscan2
- FAM135B | c.2034A>G p.R678= | Silent (SNP) | VAF 60/144 reads (42%) | catalogued as COSV52745746; called by muse, mutect2, varscan2
- FAM13A | c.2346G>A p.E782= | Silent (SNP) | VAF 90/213 reads (42%) | catalogued as COSV52010501; called by muse, mutect2, varscan2
- FAM161A | c.115C>T p.L39= | Silent (SNP) | VAF 41/77 reads (53%) | catalogued as COSV56768146; called by muse, mutect2, varscan2
- FAM47C | c.90C>T p.F30= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV63727012; called by muse, mutect2, varscan2
- FAM53A | c.1146C>T p.V382= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as COSV57402886; called by muse, mutect2, varscan2
- FAT3 | c.12468C>T p.I4156= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs771087151, COSV53095593; called by muse, mutect2, varscan2
- FHOD1 | c.1587C>T p.I529= | Silent (SNP) | VAF 83/156 reads (53%) | catalogued as COSV50758704, COSV50766466; called by muse, mutect2, varscan2
- FREM1 | c.367C>T p.L123= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as COSV66528131; called by muse, mutect2, varscan2
- FZD2 | c.1245C>T p.F415= | Silent (SNP) | VAF 34/130 reads (26%) | catalogued as COSV59529871; called by muse, mutect2, varscan2
- GALNT17 | c.429G>A p.K143= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as COSV61182394; called by muse, mutect2, varscan2
- GCN1 | c.5217C>T p.I1739= | Silent (SNP) | VAF 130/297 reads (44%) | catalogued as rs752430496, COSV56105740, COSV56111131; called by muse, mutect2, varscan2
- GHR | c.1113G>A p.E371= | Silent (SNP) | VAF 70/158 reads (44%) | catalogued as COSV50123930; called by muse, mutect2, varscan2
- GLRA4 | c.537C>T p.F179= | Silent (SNP) | VAF 53/62 reads (85%) | catalogued as COSV65456655; called by muse, mutect2, varscan2
- GNE | c.1312C>T p.L438= (on ENST00000396594 / NM_001128227.3; = p.L407= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV64952710; called by muse, mutect2, varscan2
- GOLGA1 | c.720G>A p.L240= | Silent (SNP) | VAF 63/190 reads (33%) | catalogued as COSV65230768; called by muse, mutect2, varscan2
- GPR146 | c.435G>A p.R145= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs1218756803, COSV52466907; called by muse, mutect2, varscan2
- GRIK3 | c.1413G>A p.K471= | Silent (SNP) | VAF 107/224 reads (48%) | catalogued as COSV66142462, COSV66144876; called by muse, mutect2, varscan2
- GRM3 | c.51G>A p.K17= | Silent (SNP) | VAF 45/128 reads (35%) | catalogued as COSV64467172, COSV64477642; called by muse, mutect2, varscan2
- GSK3B | c.540G>A p.R180= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs200166474, COSV51780856; called by muse, mutect2, varscan2
- HCLS1 | c.963G>A p.R321= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV57522714; called by muse, mutect2, varscan2
- HEATR5A | c.1194C>T p.A398= | Silent (SNP) | VAF 51/125 reads (41%) | catalogued as rs547560643, COSV101120522, COSV66341757; called by muse, mutect2, varscan2
- HELZ2 | c.4914C>T p.L1638= (on ENST00000467148 / NM_001037335.2; = p.L1069= on NM_033405.3) | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV71296718; called by muse, mutect2
- HERC2 | c.10296C>T p.S3432= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV55342819; called by muse, mutect2
- HGFAC | c.66C>T p.L22= | Silent (SNP) | VAF 46/80 reads (58%) | catalogued as rs760618805, COSV58749387, COSV58755616; called by muse, mutect2, varscan2
- HGSNAT | c.396T>C p.F132= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV65535024; called by muse, varscan2
- HHAT | c.552C>T p.S184= | Silent (SNP) | VAF 62/110 reads (56%) | catalogued as COSV54806273; called by muse, mutect2, varscan2
- HMCN1 | c.13572C>T p.V4524= | Silent (SNP) | VAF 87/241 reads (36%) | catalogued as COSV54928861; called by muse, mutect2, varscan2
- HMCN1 | c.14112G>A p.A4704= | Silent (SNP) | VAF 90/286 reads (31%) | catalogued as rs780178233, COSV54928876; called by muse, mutect2, varscan2
- HMCN1 | c.16656C>T p.I5552= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV54928889; called by mutect2, varscan2
- HNRNPA0 | c.381C>T p.A127= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV100152898; called by muse, mutect2, varscan2
- HNRNPUL2 | c.2106C>T p.Y702= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs201898472; called by muse, mutect2, varscan2
- HRNR | c.6585C>T p.S2195= | Silent (SNP) | VAF 91/778 reads (12%) | catalogued as rs755180448, COSV64260196; called by muse, varscan2
- HSPH1 | c.2454C>T p.G818= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV60713013; called by muse, mutect2, varscan2
- HYDIN | c.1950C>G p.R650= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as rs757662209, COSV55495314; called by muse, mutect2, varscan2
- IFT172 | c.4197C>T p.F1399= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as COSV53137495; called by muse, mutect2, varscan2
- IGHV2-26 | c.72G>A p.K24= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs1354543355; called by muse, mutect2, varscan2
- IKBKB | c.1203C>T p.I401= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV60599113; called by muse, mutect2, varscan2
- IMPDH2 | c.522C>T p.F174= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs936958196, COSV58708754; called by muse, mutect2, varscan2
- INHBB | c.663C>T p.L221= | Silent (SNP) | VAF 94/173 reads (54%) | catalogued as COSV54678906; called by muse, mutect2, varscan2
- JAG1 | c.777C>T p.G259= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV54761279; called by muse, mutect2, varscan2
- KCNMB2 | c.666C>T p.Y222= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV64201800; called by muse, mutect2, varscan2
- KIF1C | c.2499C>T p.L833= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV100297086, COSV57906812; called by muse, mutect2, varscan2
- KRT15 | c.1353C>T p.S451= | Silent (SNP) | VAF 72/136 reads (53%) | catalogued as COSV54181099; called by muse, mutect2, varscan2
- KRT37 | c.711C>T p.S237= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1192531279, COSV56659519; called by muse, mutect2, varscan2
- KRT5 | c.1740C>T p.T580= | Silent (SNP) | VAF 61/127 reads (48%) | catalogued as COSV52858882; called by muse, mutect2, varscan2
- LAMA2 | c.6466C>A p.R2156= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as CM142796, COSV70351394, COSV70353032; called by muse, mutect2, varscan2
- LCE3D | c.108C>T p.G36= | Silent (SNP) | VAF 73/206 reads (35%) | catalogued as rs749864603, COSV64231099; called by muse, mutect2, varscan2
- LDB1 | c.852C>T p.P284= (on ENST00000425280 / NM_001321612.2; = p.P248= on NM_003893.5) | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV100756375; called by muse, mutect2, varscan2
- LHX4 | c.243C>T p.F81= | Silent (SNP) | VAF 49/89 reads (55%) | catalogued as rs774861553, COSV55377396; called by muse, mutect2, varscan2
- LILRB4 | c.117C>T p.I39= | Silent (SNP) | VAF 39/117 reads (33%) | catalogued as rs746082594, COSV54407781; called by muse, mutect2, varscan2
- LNPK | c.309A>G p.E103= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV55825718; called by muse, mutect2, varscan2
- LPA | c.5394C>T p.L1798= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV60308559; called by muse, mutect2, varscan2
- LPA | c.4314G>A p.R1438= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV60308568; called by muse, mutect2, varscan2
- LRP1 | c.11079C>T p.F3693= | Silent (SNP) | VAF 30/212 reads (14%) | catalogued as rs758673863, COSV54521239; called by muse, mutect2, varscan2
- LRP1 | c.11652C>T p.G3884= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV54517430, COSV99675556; called by muse, mutect2, varscan2
- LRRC45 | c.297G>A p.R99= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs763083316, COSV100141791; called by muse, mutect2, varscan2
- MAEA | c.993C>T p.A331= (on ENST00000303400 / NM_001017405.3; = p.A290= on NM_005882.5) | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV53264217; called by muse, mutect2, varscan2
- MAGEC1 | c.645G>A p.Q215= | Silent (SNP) | VAF 117/358 reads (33%) | catalogued as COSV53578969; called by muse, mutect2, varscan2
- MBD4 | c.357A>G p.R119= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV51445503; called by muse, mutect2, varscan2
- MBP | c.642C>T p.T214= (on ENST00000355994 / NM_001025101.2; = p.T107= on NM_002385.3) | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV62830132; called by muse, mutect2, varscan2
- MDN1 | c.6399C>T p.L2133= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as rs1490708814, COSV65521732; called by muse, mutect2, varscan2
- MDN1 | c.1944C>T p.F648= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV65527973; called by muse, mutect2, varscan2
- MFSD2B | c.456C>T p.F152= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV57855877, COSV57855935; called by muse, mutect2, varscan2
- MID1 | c.1819C>T p.L607= | Silent (SNP) | VAF 115/126 reads (91%) | catalogued as COSV58198037; called by muse, mutect2, varscan2
- MINK1 | c.2757C>T p.P919= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV53419425; called by muse, mutect2, varscan2
- MRGPRD | c.204G>A p.L68= | Silent (SNP) | VAF 34/49 reads (69%) | catalogued as COSV58423934; called by muse, mutect2, varscan2
- MROH9 | c.888G>A p.K296= | Silent (SNP) | VAF 49/189 reads (26%) | catalogued as COSV63012741; called by muse, mutect2, varscan2
- MUC3A | c.8067C>T p.I2689= | Silent (SNP) | VAF 129/1169 reads (11%) | catalogued as COSV60222520; called by muse, mutect2, varscan2
- MUC5AC | c.405G>A p.R135= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV62255090; called by muse, mutect2, varscan2
- MUC5B | c.15315C>T p.I5105= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV71594553; called by muse, mutect2, varscan2
- MXI1 | c.627G>A p.P209= | Silent (SNP) | VAF 33/53 reads (62%) | catalogued as rs767851111, COSV53291070; called by muse, mutect2, varscan2
- MYH1 | c.4467G>A p.K1489= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV56854740; called by muse, mutect2, varscan2
- MYH11 | c.1566C>A p.I522= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV55561912, COSV55564671; called by muse, mutect2, varscan2
- MYH11 | c.1410C>T p.S470= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV55564692; called by muse, mutect2, varscan2
- MYH2 | c.4740G>A p.R1580= | Silent (SNP) | VAF 88/173 reads (51%) | catalogued as COSV55431125; called by muse, mutect2, varscan2
- MYO15A | c.495C>T p.S165= | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as COSV52762721; called by muse, mutect2, varscan2
- MYT1L | c.2295G>A p.V765= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as rs1345933668, COSV67728923; called by muse, mutect2, varscan2
- N4BP2L2 | c.2214C>T p.T738= (on ENST00000674422; = p.T309= on NM_033111.4) | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV62634747; called by muse, mutect2, varscan2
- NAALAD2 | c.837C>T p.I279= | Silent (SNP) | VAF 44/60 reads (73%) | catalogued as rs1470224690, COSV58959892; called by muse, mutect2, varscan2
- NF1 | c.2500C>T p.L834= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV62214986; called by muse, mutect2, varscan2
- NFYC | c.1359C>T p.P453= (on ENST00000308733 / NM_001308114.1; = p.P330= on NM_014223.5) | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as COSV100438393; called by muse, mutect2, varscan2
- NISCH | c.1431C>T p.S477= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV61901705; called by muse, mutect2, varscan2
139 further variants in this file (0 protein-altering or splice-affecting, 122 silent, 17 other) are not listed here.
